Gene-level copy-number profile of tumor specimen TCGA-DU-A7T8-01A from TCGA case TCGA-DU-A7T8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.9 years (13,108 days).
Specimen TCGA-DU-A7T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.3caffdac-e2bd-48c0-ade0-fad107fb1ac9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-A7T8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f66ac05a-2f47-4249-81a6-add8e0be32d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 6,384; copy number 2: 50,956; copy number 4: 2,389.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-A7T8-01A-21D-A34I-01): tumor purity 0.79, ploidy 4.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:31,118,416–33,491,716, 61 genes (within-gene range 0–2) (broad region; genes not listed).
- chr21:43,865,223–44,348,295, 24 genes (within-gene range 0–2): AGPAT3, RNU6-859P, AP001054.1, RNU6-1150P, TRAPPC10, H2AZP1, PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1, AIRE, PFKL, AP001062.3, CFAP410, AP001062.1, AP001062.2, AP001063.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,003. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
